Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4VC, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4VC-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: UTERUS, CERVIX AND BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (418 GRAMS) -

- A. MALIGNANT MÜLLERIAN MIXED TUMOR (MMMT) OF ENDOMETRIUM (see comment).
- B. THE ENDOMETRIOID CARCINOMATOUS COMPONENT IS FIGO GRADE 3, NUCLEAR GRADE 3.
- C. THE TUMOR INVADIES 100% OF THE MYOMETRIAL THICKNESS AND THROUGH UTERINE SEROSA WITH EXTENSIVE NECROSIS.
- D. THE TUMOR INVOLVES GREATER THAN 90% OF THE ENDOMETRIAL SURFACE.
- E. THE TUMOR INVOLVES ENDOCERVICAL MUCOSA.
- F. LYMPHOVASCULAR SPACE INVASION IS PRESENT.
- G. THE BACKGROUND ENDOMETRIUM IS ATROPHIC.
- H. THE MYOMETRIUM SHOWS ADENOMYOSIS AND LEIOMYOMAS.
- I. ALL ADNEXA ARE BENIGN.
- J. PELVIC WASHING IS POSITIVE FOR TUMOR CELLS
- K. STAGE: pT3a N0 MX.

ICD 6-3
Carcinosarcoma / Mixed
Mullerian Tumor, malignant
8950/3
Site: Corpus Uteri,
Endometrium C54.1
QW 3/28/13

PART 2: PELVIC LYMPH NODES, LEFT, DISSECTION -
NINE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/9).

PART 3: PELVIC LYMPH NODE, RIGHT, DISSECTION -
FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).

PART 4: PERIAORTIC LYMPH NODES, LEFT, DISSECTION -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: OMENTUM, BIOPSY -
BENIGN FIBROADIPOSE TISSUE.

COMMENT:

The tumor consists largely of a high-grade endometrioid carcinomatous component and approximately 10-20% of homologous sarcomatous component (slides 1D, 1I and 1M).

Microscopic examination substantiates the above diagnosis.

IMMUNOHISTOCHEMISTRY REPORT

Antigen/Antibody	Result
actin, muscle specific	positive in sarcomatous component
AE1/AE3	positive in carcinomatous component
CAM 5.2	positive in carcinomatous component and focally in sarcomatous component
desmin	positive in sarcomatous component
vimentin	positive in sarcomatous component

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Carcinosarcoma (malignant mixed mesodermal tumor)

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 3

TUMOR SIZE:

Maximum dimension: 10 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 90 %

DEPTH OF INVASION**:

Into serosa

STRUCTURES INVOLVED:

Endocervical glands

ANGIOLYMPHATIC INVASION:

Yes

OTHER:

(epithelial, smooth muscle, others), Adenomyosis, Leiomyoma

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 15

T STAGE, PATHOLOGIC:

pT3a

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIIA

Case No.	W 12/31/12	Yes	No
Case Discrepancy			
Primary vs. Repeat Site Discrepancy			
ICD-9 vs. ICD-10 Discrepancy			
ICD-9 vs. ICD-10 Discrepancy			
Qualifying Primary vs. Repeat			

Source: NCI Genomic Data Commons file aca0ea61-f3de-459e-b1d3-fe1951b0ff8c (TCGA-N6-A4VC.543944F8-C7D6-4757-B9B9-01891EE30B74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).